Somatic mutation profile of tumor specimen 0DUNPC from CCDI case PBCKSN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Gastrointestinal stromal tumor, benign; Tissue or organ of origin: Body of stomach; Age at diagnosis: 11.9 years (4,347 days).
Specimen 0DUNPC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31f9a9af-190d-4f3f-b221-e2d8e87734c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUNOY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f64ffde-1ae8-4a43-9ba8-f6815fa6a164

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 28/752 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CDHR4 | c.281T>C p.V94A | Missense Mutation (SNP) | VAF 99/380 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PKD1L2 | c.2254G>T p.A752S | Missense Mutation (SNP) | VAF 99/436 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- TTC28 | c.1188T>C p.A396= | Silent (SNP) | VAF 32/454 reads (7%) | called by muse, mutect2
- AHSA1 | c.792+95T>A | Intron (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- ARHGAP12 | c.*97T>A | 3'UTR (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
